Somatic mutation profile of tumor specimen TCGA-12-1597-01B (aliquot TCGA-12-1597-01B-01D-1495-08) from TCGA case TCGA-12-1597, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 62.6 years (22,865 days).
Specimen TCGA-12-1597-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b591e489-c6f7-467c-a2ec-ee6e7b51d065.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-12-1597-10A (Blood Derived Normal), aliquot TCGA-12-1597-10A-01D-1495-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/63a8bde0-97ff-4baa-8cc5-96a3ee8d913a

The open-access MAF lists 63 somatic variants for this specimen: 46 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 15, Frame Shift Del 3, In Frame Ins 1, RNA 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP4A | c.1948G>A p.E650K | Missense Mutation (SNP) | VAF 107/311 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.832); catalogued as rs779455265, COSV52870058; called by muse, mutect2, varscan2
- ATP9A | c.2644A>G p.T882A | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV58769431; called by muse, mutect2, varscan2
- BCL6B | c.1039C>T p.R347C | Missense Mutation (SNP) | VAF 58/161 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as rs747226288, COSV53428784; called by muse, mutect2, varscan2
- CFAP47 | c.4727C>T p.S1576L | Missense Mutation (SNP) | VAF 52/133 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs753159618, COSV57975366; called by muse, mutect2, varscan2
- DGKD | c.2200G>A p.G734S (on ENST00000264057 / NM_152879.3; = p.G690S on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.185); catalogued as rs145038453, COSV99895522; called by muse, mutect2, varscan2
- DGKK | c.1126G>T p.D376Y | Missense Mutation (SNP) | VAF 13/162 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1308085573, COSV101052978, COSV65708315; called by muse, mutect2
- DLC1 | c.4238A>G p.Q1413R (on ENST00000276297 / NM_001348081.2; = p.Q976R on NM_006094.5) | Missense Mutation (SNP) | VAF 83/226 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as rs1168763457, COSV52316776; called by muse, mutect2, varscan2
- DTYMK | c.496del p.Q166Sfs*3 | Frame Shift Del (DEL) | VAF 84/241 reads (35%) | catalogued as COSV59871584; called by mutect2, pindel, varscan2
- ERICH3 | c.2881G>C p.D961H | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs757938854, COSV58612998; called by muse, mutect2
- ERICH3 | c.1841G>T p.S614I | Missense Mutation (SNP) | VAF 57/160 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV58606474, COSV58613005; called by muse, mutect2, varscan2
- EXOSC8 | c.359A>C p.Q120P | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.082); catalogued as COSV53509701; called by muse, mutect2, varscan2
- FAM47C | c.2138G>T p.S713I | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.446); catalogued as COSV63728886; called by muse, mutect2, varscan2
- FANCM | c.17G>A p.R6K | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.201); catalogued as rs1464500995, COSV53533217, COSV99360924; called by muse, mutect2, varscan2
- FBXO31 | c.1051C>G p.R351G | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.231); catalogued as COSV61147955, COSV61150031; called by muse, mutect2, varscan2
- FLNB | c.7010A>C p.E2337A | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV55887557; called by muse, mutect2, varscan2
- GPR35 | c.352G>A p.V118M | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs775602865, COSV60576857; called by muse, mutect2, varscan2
- KRT4 | c.359C>A p.T120N | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as rs201805600, COSV53405497; ClinVar: likely benign; called by muse, mutect2, varscan2
- MCAT | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV51793167; called by muse, mutect2, varscan2
- MED12 | c.1303G>C p.V435L | Missense Mutation (SNP) | VAF 51/99 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as COSV61348624; called by muse, mutect2, varscan2
- MGA | c.4474C>T p.R1492C | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs778522495, COSV54949325; called by muse, mutect2, varscan2
- MRGBP | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 57/296 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.478); catalogued as rs1461277194, COSV100978308, COSV65111613; called by muse, mutect2, varscan2
- MRGPRE | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT tolerated (0.1); PolyPhen benign (0.391); catalogued as rs754926111, COSV67745840; called by muse, mutect2
- MTCP1 | c.127C>T p.R43* | Nonsense Mutation (SNP) | VAF 63/145 reads (43%) | catalogued as COSV62900070; called by muse, mutect2, varscan2
- MYT1L | c.1357G>A p.A453T | Missense Mutation (SNP) | VAF 104/223 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.268); catalogued as COSV67726707; called by muse, mutect2, varscan2
- NGF | c.586C>T p.H196Y | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV65688382; called by muse, mutect2, varscan2
- NXPE4 | c.734G>T p.R245M | Missense Mutation (SNP) | VAF 73/148 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV64944115; called by muse, mutect2, varscan2
- OBSCN | c.6952G>A p.A2318T | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.999); catalogued as rs758890771, COSV52802214; called by muse, mutect2, varscan2
- OR2M4 | c.908A>T p.K303M | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV60709033; called by muse, mutect2
- OR8K3 | c.243G>A p.M81I | Missense Mutation (SNP) | VAF 48/227 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.078); catalogued as rs905125363, COSV100449700, COSV57132293; called by muse, mutect2, varscan2
- PAH | c.821A>T p.K274M | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.025); catalogued as COSV61018815; called by muse, mutect2, varscan2
- PGBD1 | c.2093G>A p.C698Y | Missense Mutation (SNP) | VAF 85/209 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52554882; called by muse, mutect2, varscan2
- PGM5 | c.563C>A p.P188Q | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.929); catalogued as COSV67164614; called by muse, mutect2, varscan2
- PTEN | c.731del p.P244Lfs*12 | Frame Shift Del (DEL) | VAF 55/97 reads (57%) | catalogued as COSV64306633; called by mutect2, pindel, varscan2
- RNF157 | c.958C>T p.R320W | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747444288, COSV53946661; called by muse, mutect2, varscan2
- SMAD7 | c.1166del p.P389Rfs*12 | Frame Shift Del (DEL) | VAF 18/52 reads (35%) | catalogued as COSV100053049; called by mutect2, pindel, varscan2
- SNRNP200 | c.2215C>T p.R739W | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs780925650, COSV60492463, COSV60493574; called by muse, mutect2, varscan2
- SPEG | c.5533G>A p.A1845T | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.642); catalogued as rs759067349, COSV56675331; called by muse, mutect2, varscan2
- SPTA1 | c.1403G>A p.R468H | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs372937123, COSV63757170; called by muse, mutect2, varscan2
- SSH2 | c.1105G>T p.A369S | Missense Mutation (SNP) | VAF 18/165 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.176); catalogued as COSV52176935; called by muse, mutect2, varscan2
- ST6GAL2 | c.186G>A p.M62I | Missense Mutation (SNP) | VAF 24/50 reads (48%) | PolyPhen benign (0.164); catalogued as COSV64530228; called by muse, mutect2, varscan2
- TAF7L | c.1249G>T p.D417Y | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.342); catalogued as COSV61256949; called by muse, mutect2, varscan2
- TRPV6 | c.1052C>T p.T351M | Missense Mutation (SNP) | VAF 51/178 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs777616496, COSV63892749; called by muse, mutect2, varscan2
- TTN | c.56767G>A p.V18923I (on ENST00000591111; = p.V11499I on NM_003319.4) | Missense Mutation (SNP) | VAF 53/144 reads (37%) | PolyPhen probably damaging (0.991); catalogued as rs761270633, COSV60207633; ClinVar: likely benign; called by muse, mutect2, varscan2
- TTN | c.22556T>C p.I7519T (on ENST00000591111; = p.I6592T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/132 reads (46%) | PolyPhen benign (0.116); catalogued as COSV60207678; called by muse, mutect2, varscan2
- VSTM4 | c.580C>T p.L194F | Missense Mutation (SNP) | VAF 41/55 reads (75%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV60528404; called by muse, mutect2, varscan2
- WDR1 | c.270_275dup p.E91_H92insQE | In Frame Ins (INS) | VAF 29/83 reads (35%) | called by mutect2, varscan2
- ADAM2 | c.1869T>C p.D623= | Silent (SNP) | VAF 40/156 reads (26%) | catalogued as rs1208959681, COSV55865400; called by muse, mutect2, varscan2
- APOBEC3A | c.135G>A p.S45= | Silent (SNP) | VAF 31/88 reads (35%) | catalogued as rs193155851; called by muse, mutect2, varscan2
- BRINP3 | c.2244G>A p.A748= | Silent (SNP) | VAF 83/214 reads (39%) | catalogued as rs562180986, COSV66514032; called by muse, mutect2, varscan2
- CPZ | c.570C>T p.Y190= (on ENST00000360986 / NM_001014447.3; = p.Y179= on NM_003652.3) | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as rs537441827, COSV59924402; called by muse, mutect2, varscan2
- FAM98A | c.1044C>T p.Y348= | Silent (SNP) | VAF 29/104 reads (28%) | catalogued as rs34080556; called by muse, mutect2, varscan2
- FGF16 | c.486C>T p.Y162= | Silent (SNP) | VAF 30/145 reads (21%) | catalogued as COSV71546146; called by muse, mutect2, varscan2
- HCN1 | c.2253G>A p.P751= | Silent (SNP) | VAF 26/59 reads (44%) | catalogued as COSV57496113; called by muse, varscan2
- KCNN2 | c.816C>T p.V272= (on ENST00000264773; = p.V484= on NM_021614.4) | Silent (SNP) | VAF 39/202 reads (19%) | catalogued as COSV53294374; called by muse, mutect2, varscan2
- KRTAP10-8 | c.276C>T p.D92= | Silent (SNP) | VAF 61/130 reads (47%) | catalogued as COSV58166835; called by muse, mutect2, varscan2
- MAP4K2 | c.2238C>T p.I746= | Silent (SNP) | VAF 31/88 reads (35%) | catalogued as rs746314836, COSV53646152; called by muse, mutect2, varscan2
- OR6C1 | c.210G>A p.S70= | Silent (SNP) | VAF 51/131 reads (39%) | catalogued as rs375702387; called by muse, mutect2, varscan2
- PPP1R3A | c.1884T>C p.N628= | Silent (SNP) | VAF 68/238 reads (29%) | catalogued as rs911143253, COSV52888022; called by muse, mutect2, varscan2
- SRPK3 | c.1317A>G p.E439= | Silent (SNP) | VAF 52/136 reads (38%) | catalogued as COSV54209032; called by muse, mutect2, varscan2
- TTPA | c.213A>G p.K71= | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as COSV52647586; called by muse, mutect2
- WNK2 | c.6675G>A p.A2225= (on ENST00000297954 / NM_001282394.1; = p.A2188= on NM_006648.3) | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as rs756768259, COSV52951537; called by muse, mutect2, varscan2
- GNAO1 | c.723+4012C>G | Intron (SNP) | VAF 208/470 reads (44%) | catalogued as COSV52617488; called by muse, mutect2, varscan2
- SNORD114-25 | n.41G>A | RNA (SNP) | VAF 70/170 reads (41%) | catalogued as rs769019053; called by muse, varscan2
